Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A74H, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A74H-01A (Primary Tumor).

Pathology Report for**Date of Surgery:****Diagnosis:**

Left temporal brain tumor
Anaplastic astrocytoma, grade 3
P53: focally positive
IDH1: Negative
MIB-1 LI: 13.3%

Discussion:

The neoplastic cells are negative for IDH1 with a minority expressing p53. MIB-1 reactivity areas are seen within the tumor but in the most proliferative areas a labeling index of 13.3% is calculated, consistent with a high grade astrocytoma.

Microscopic Description:

Sections demonstrate a diffusely infiltrative astrocytic neoplasm. Atypia ranges from mild to moderate. There is mild to moderate hypercellularity. The tumor cells resemble fibrillary astrocytes. Some areas are suggestive, but not definitive, for perinuclear halos. A careful examination only reveals a rare mitotic figure. There is no microvascular proliferation or necrosis.

W 8/1/13

Source: NCI Genomic Data Commons file 3045e3df-9c08-4737-885c-36fd6fb54b74 (TCGA-HT-A74H.436222D6-7870-4C4A-8F3A-50562E9AB8A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).